Somatic mutation profile of tumor specimen CDDP-ABKD-TTP1-A (aliquot CDDP-ABKD-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABKD, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74 years.
Specimen CDDP-ABKD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26a342cd-a2d1-4437-8186-befe72703bbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABKD-NB1-A (Blood Derived Normal), aliquot CDDP-ABKD-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1a37a40-e67b-4922-85bd-8dc607bb00f7

The open-access MAF lists 162 somatic variants for this specimen: 97 protein-altering or splice-affecting, 36 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 36, Intron 14, RNA 7, Nonsense Mutation 7, Frame Shift Del 6, Splice Site 3, 3'UTR 2, 5'UTR 2, 5'Flank 2, Splice Region 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.843del p.L282Sfs*5 | Frame Shift Del (DEL) | VAF 28/116 reads (24%) | catalogued as rs587776656, CD982962, COSV58821884, COSV58823674, COSV58823877; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAMTSL3 | c.4882A>T p.R1628W | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV54436064; called by muse, mutect2
- APBA1 | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV55221557; called by muse, mutect2, varscan2
- CBX2 | c.851G>A p.C284Y | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV53968438; called by muse, mutect2
- CD93 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV55663170; called by muse, mutect2
- CDRT1 | c.737A>G p.D246G | Missense Mutation (SNP) | VAF 81/737 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1210373755; called by muse, mutect2, varscan2
- CHD9 | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV68297020; called by muse, mutect2, varscan2
- DCDC2 | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 42/334 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs772638721; called by muse, mutect2, varscan2
- DNAAF3 | c.72C>A p.D24E (on ENST00000524407 / NM_001256715.2; = p.D71E on NM_178837.4) | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs200866175, COSV100845908, COSV62829702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.10137T>C p.N3379= | Splice Region (SNP) | VAF 7/52 reads (13%) | catalogued as COSV59424636; called by muse, mutect2, varscan2
- EVC | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs775052481; ClinVar: uncertain significance; called by muse, mutect2
- FZD7 | c.1197G>T p.M399I | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV53808223; called by muse, mutect2, varscan2
- GJA5 | c.407G>T p.W136L | Missense Mutation (SNP) | VAF 280/1132 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as COSV54782869, COSV54783976; called by muse, varscan2
- GLRA3 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV99927617; called by muse, mutect2
- GOLGB1 | c.3840A>C p.L1280F | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.347); catalogued as COSV61461711; called by muse, mutect2, varscan2
- GRIN2B | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV74204764; called by muse, mutect2, varscan2
- HMCN1 | c.5488T>G p.S1830A | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as COSV54876692; called by muse, mutect2, varscan2
- HOXA2 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 64/506 reads (13%) | catalogued as COSV56067441; called by muse, mutect2, varscan2
- IL12RB2 | c.979G>T p.V327F | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV52020209; called by muse, mutect2, varscan2
- ITM2B | c.722A>G p.Q241R | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs1566164812; called by muse, mutect2, varscan2
- KEAP1 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50261251, COSV50263549; called by muse, mutect2, varscan2
- KIF18B | c.1733C>T p.P578L (on ENST00000593135 / NM_001265577.2; = p.P590L on NM_001264573.2) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1181651315, COSV59270698; called by muse, mutect2
- KLC4 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 18/232 reads (8%) | catalogued as rs746914286; called by muse, mutect2
- MRPL45 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.186); catalogued as rs761623144; called by muse, mutect2
- MTG1 | c.889A>G p.N297D | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as rs1012782520, COSV58152514; called by muse, mutect2, varscan2
- MTTP | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV99644726; called by muse, mutect2
- MYH6 | c.3701C>T p.T1234I | Missense Mutation (SNP) | VAF 149/894 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs750141267; called by muse, mutect2, varscan2
- MYOM2 | c.4031G>A p.G1344D | Missense Mutation (SNP) | VAF 24/491 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50702103; called by muse, mutect2
- NAA25 | c.472A>G p.M158V | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV55701905; called by muse, mutect2, varscan2
- NEDD1 | c.1085G>C p.G362A | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57141484; called by muse, mutect2, varscan2
- NLRP8 | c.1854G>T p.E618D | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.338); catalogued as COSV52583306; called by muse, mutect2, varscan2
- NPBWR2 | c.936C>A p.N312K | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100871114, COSV63899779; called by muse, mutect2, varscan2
- NSUN2 | c.1149C>G p.S383R | Missense Mutation (SNP) | VAF 90/345 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV52952477; called by muse, mutect2, varscan2
- OCA2 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 45/534 reads (8%) | catalogued as rs959570803; called by muse, mutect2
- OR4N2 | c.421T>A p.C141S | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV60049965; called by muse, mutect2
- OSBPL5 | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 28/336 reads (8%) | catalogued as rs762218026; called by muse, mutect2
- P2RX1 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV56652854; called by muse, mutect2
- PCDH15 | c.5297C>A p.A1766E | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated, low confidence (1); catalogued as COSV64705505; called by muse, mutect2, varscan2
- PCDHA5 | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.868); catalogued as rs782808800, COSV65349286; called by muse, mutect2
- PCDHB16 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 222/1007 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs1371346092, COSV53357605; called by muse, mutect2, varscan2
- POU5F1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 34/777 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1271010739; called by muse, mutect2
- RB1CC1 | c.3967T>G p.S1323A | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1455946210; called by muse, mutect2, varscan2
- RRBP1 | c.2290G>A p.A764T (on ENST00000377813 / NM_001365613.2; = p.A331T on NM_004587.3) | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55695519; called by muse, mutect2, varscan2
- RSRC2 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs751748810, COSV59204664; called by muse, mutect2
- RUFY3 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56912178; called by muse, mutect2
- RXFP2 | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV53633003; called by muse, mutect2, varscan2
- SLC17A2 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs776445761, COSV55350281; called by muse, mutect2, varscan2
- SLC6A11 | c.1384A>G p.I462V | Missense Mutation (SNP) | VAF 72/335 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs773059470, COSV54389723; called by muse, mutect2, varscan2
- SPHKAP | c.1475C>G p.P492R | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100764121; called by muse, mutect2
- TEX13C | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 110/309 reads (36%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); catalogued as COSV51042773; called by muse, mutect2, varscan2
- TRAPPC9 | c.842C>G p.A281G | Missense Mutation (SNP) | VAF 89/777 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs760487696; called by muse, mutect2, varscan2
- TRIM71 | c.2204A>G p.N735S | Missense Mutation (SNP) | VAF 89/443 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as COSV67470119; called by muse, mutect2, varscan2
- TTN | c.11695T>G p.S3899A (on ENST00000591111; = p.S3853A on NM_003319.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV59884947; called by muse, mutect2, varscan2
- TWSG1 | c.124-2A>G p.X42_splice | Splice Site (SNP) | VAF 35/123 reads (28%) | catalogued as rs1439772663; called by muse, mutect2, varscan2
- UBE2F | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs759828162, COSV56024755; called by muse, mutect2
- USP32 | c.3387A>T p.L1129F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV56263993; called by muse, mutect2, varscan2
- XPO7 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV53010651, COSV99380621; called by muse, mutect2
- ZNF383 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV61938563; called by muse, mutect2, varscan2
- ZNF500 | c.460G>T p.G154* | Nonsense Mutation (SNP) | VAF 22/98 reads (22%) | catalogued as COSV54787016; called by muse, mutect2, varscan2
- ZNF93 | c.323A>G p.H108R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs1288935905; called by muse, mutect2
- ATM | c.3715_3716dup p.L1239Ffs*2 | Frame Shift Ins (INS) | VAF 17/152 reads (11%) | called by mutect2, pindel, varscan2
- ATP8B2 | c.1526C>G p.T509S (on ENST00000672630; = p.T476S on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD177 | c.1178G>T p.R393L | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CHM | c.1300G>T p.V434L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CREBBP | c.5012C>T p.A1671V | Missense Mutation (SNP) | VAF 78/731 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CUX2 | c.1728dup p.G577Wfs*43 | Frame Shift Ins (INS) | VAF 34/287 reads (12%) | called by mutect2, pindel, varscan2
- DIO2 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.701); called by muse, mutect2
- DLGAP3 | c.165_183del p.H56Pfs*2 | Frame Shift Del (DEL) | VAF 32/331 reads (10%) | called by mutect2, pindel
- DNAH9 | c.2429A>T p.N810I | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAM83C | c.334A>C p.T112P | Missense Mutation (SNP) | VAF 33/337 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GGNBP2 | c.1021-2A>C p.X341_splice | Splice Site (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2
- GSAP | c.743T>G p.F248C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- IGF2R | c.7369_7371del p.E2457del | In Frame Del (DEL) | VAF 24/212 reads (11%) | called by mutect2, pindel, varscan2
- IGKV3D-20 | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- IQCA1 | c.2234A>T p.H745L | Missense Mutation (SNP) | VAF 54/540 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2
- LY6G6C | c.209A>C p.E70A | Missense Mutation (SNP) | VAF 60/518 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- MMEL1 | c.1097del p.L366Rfs*46 | Frame Shift Del (DEL) | VAF 110/361 reads (30%) | called by mutect2, pindel, varscan2
- NID2 | c.129G>T p.W43C | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.319); called by muse, mutect2
- OR2L2 | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); called by muse, mutect2
- OR5H6 | c.116_117del p.C39* (on ENST00000642105; = p.C23* on NM_001005479.2) | Frame Shift Del (DEL) | VAF 33/156 reads (21%) | called by mutect2, pindel, varscan2
- OR8H1 | c.226G>C p.V76L | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- OSBPL5 | c.426G>T p.W142C | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHLPP1 | c.3167T>C p.M1056T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2
- POTED | c.1600G>C p.A534P | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RCVRN | c.390C>G p.F130L | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RFC1 | c.1826A>G p.N609S | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- RGPD3 | c.2071A>G p.K691E | Missense Mutation (SNP) | VAF 21/390 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.584); called by muse, mutect2
- SCN7A | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SHANK3 | c.727_730del p.L243Gfs*136 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, varscan2
- SIGLEC12 | c.1511C>A p.S504Y (on ENST00000291707 / NM_053003.4; = p.S386Y on NM_033329.2) | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- STPG2 | c.529A>T p.T177S | Missense Mutation (SNP) | VAF 18/138 reads (13%) | called by muse, varscan2
- TH | c.789-4G>C | Splice Region (SNP) | VAF 22/262 reads (8%) | called by muse, mutect2
- TRPM1 | c.3230A>G p.N1077S | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- UNC45B | c.1719C>G p.Y573* | Nonsense Mutation (SNP) | VAF 13/153 reads (8%) | called by muse, mutect2
- VAV1 | c.1024-2A>C p.X342_splice | Splice Site (SNP) | VAF 17/187 reads (9%) | called by muse, mutect2
- ZIM3 | c.579del p.K193Nfs*131 | Frame Shift Del (DEL) | VAF 48/360 reads (13%) | called by mutect2, pindel, varscan2
- ZNF530 | c.949C>A p.H317N | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ALDOB | c.60C>A p.A20= | Silent (SNP) | VAF 72/336 reads (21%) | catalogued as COSV66397257; called by muse, mutect2, varscan2
- AMOTL2 | c.516C>T p.A172= | Silent (SNP) | VAF 31/287 reads (11%) | catalogued as COSV51437691; called by muse, mutect2, varscan2
- ARSF | c.120G>A p.L40= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV63838949; called by muse, mutect2, varscan2
- ASXL2 | c.3942G>C p.P1314= | Silent (SNP) | VAF 60/290 reads (21%) | catalogued as rs558833597, COSV55453461; called by mutect2, varscan2
- C12orf4 | c.1413T>A p.P471= | Silent (SNP) | VAF 12/171 reads (7%) | called by muse, mutect2
- CNGB1 | c.3504C>T p.A1168= | Silent (SNP) | VAF 33/319 reads (10%) | called by muse, mutect2, varscan2
- COL4A2 | c.2709C>T p.S903= | Silent (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- EPCAM | c.195A>G p.K65= | Silent (SNP) | VAF 34/380 reads (9%) | catalogued as COSV99764101; called by muse, mutect2
- ERICH3 | c.3714C>A p.G1238= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as COSV58599095; called by muse, mutect2, varscan2
- FAAP24 | c.522T>A p.A174= | Silent (SNP) | VAF 24/382 reads (6%) | called by muse, mutect2
- H3-5 | c.258C>T p.S86= | Silent (SNP) | VAF 64/488 reads (13%) | catalogued as rs1221139151; called by muse, mutect2, varscan2
- IARS2 | c.1047G>A p.E349= | Silent (SNP) | VAF 20/355 reads (6%) | called by muse, mutect2
- IQGAP1 | c.4125G>A p.E1375= | Silent (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- LHFPL1 | c.153C>T p.N51= | Silent (SNP) | VAF 61/192 reads (32%) | catalogued as COSV64332924; called by muse, mutect2, varscan2
- NKAP | c.744A>G p.K248= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV65055921; called by muse, mutect2, varscan2
- OR13F1 | c.874C>T p.L292= | Silent (SNP) | VAF 29/198 reads (15%) | catalogued as COSV58250695; called by muse, varscan2
- OR9Q2 | c.480G>T p.T160= | Silent (SNP) | VAF 43/412 reads (10%) | catalogued as COSV61111345; called by muse, mutect2
- PEX26 | c.753C>T p.P251= | Silent (SNP) | VAF 65/727 reads (9%) | catalogued as COSV61604115; called by muse, mutect2
- PLA2G7 | c.246T>C p.R82= | Silent (SNP) | VAF 13/145 reads (9%) | called by muse, mutect2
- PRSS8 | c.600G>C p.T200= | Silent (SNP) | VAF 31/301 reads (10%) | catalogued as COSV54895060; called by muse, mutect2, varscan2
- PSG3 | c.117A>G p.E39= | Silent (SNP) | VAF 19/225 reads (8%) | catalogued as rs1375271566; called by muse, mutect2
- PTPRZ1 | c.2292T>C p.S764= | Silent (SNP) | VAF 13/134 reads (10%) | catalogued as COSV66430217; called by muse, mutect2, varscan2
- RBBP6 | c.4080C>T p.V1360= | Silent (SNP) | VAF 58/253 reads (23%) | catalogued as COSV100154680, COSV60503057; called by muse, mutect2, varscan2
- RNF20 | c.2457G>A p.G819= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- RNF31 | c.507A>T p.P169= | Silent (SNP) | VAF 20/219 reads (9%) | catalogued as COSV53758406; called by muse, mutect2
- SNX4 | c.492G>A p.R164= | Silent (SNP) | VAF 19/268 reads (7%) | called by muse, mutect2
- SOS2 | c.720C>A p.I240= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV53567993; called by muse, mutect2, varscan2
- TCP1 | c.1113G>A p.T371= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as rs200792657, COSV58457433; called by muse, varscan2
- TLN1 | c.6126G>A p.E2042= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as COSV59203996; called by muse, mutect2, varscan2
- TMEM129 | c.546C>A p.A182= | Silent (SNP) | VAF 26/361 reads (7%) | called by muse, mutect2
- VPS13B | c.10434C>A p.P3478= | Silent (SNP) | VAF 98/839 reads (12%) | catalogued as rs1444426292, COSV62133149; called by muse, mutect2, varscan2
- VWA5A | c.1890G>A p.K630= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as rs1025368057, COSV64411790; called by muse, mutect2, varscan2
- VWC2L | c.234T>C p.C78= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- YIPF7 | c.639C>T p.P213= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs1310400902; called by muse, mutect2, varscan2
- ZNF543 | c.1506T>G p.T502= | Silent (SNP) | VAF 60/350 reads (17%) | catalogued as COSV58626358; called by muse, mutect2, varscan2
- ZNF613 | c.135G>T p.V45= (on ENST00000293471 / NM_001031721.4; = p.V9= on NM_024840.4) | Silent (SNP) | VAF 15/220 reads (7%) | catalogued as COSV53271353; called by muse, mutect2
- AC104825.1 | n.1294_1344del | RNA (DEL) | VAF 135/1122 reads (12%) | catalogued as rs1560157788; called by mutect2, pindel
- ADAMTS8 | chr11:130401846 C>T | 3'Flank (SNP) | VAF 67/426 reads (16%) | called by muse, mutect2, varscan2
- AL359195.2 | n.3127C>T | RNA (SNP) | VAF 95/391 reads (24%) | called by muse, mutect2, varscan2
- ARAP1 | c.748-22G>T | Intron (SNP) | VAF 28/281 reads (10%) | called by muse, mutect2
- ARHGEF4 | c.-140G>T | 5'UTR (SNP) | VAF 24/321 reads (7%) | called by muse, mutect2
- ATAD3B | c.282+1382G>A | Intron (SNP) | VAF 21/716 reads (3%) | catalogued as rs1336307796; called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+39063_372+39091del | Intron (DEL) | VAF 94/642 reads (15%) | called by mutect2, pindel
- CD46 | c.*117A>T | 3'UTR (SNP) | VAF 41/313 reads (13%) | catalogued as COSV59731204; called by muse, mutect2, varscan2
- CDH8 | c.*5818A>T | 3'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- DEFB130C | chr11:71865819 T>C | 3'Flank (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- ECHDC2 | c.457+83T>C | Intron (SNP) | VAF 88/548 reads (16%) | catalogued as rs1405077276, COSV64300182; called by muse, mutect2, varscan2
- HAPLN3 | c.-21G>T | 5'UTR (SNP) | VAF 69/586 reads (12%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1399G>T | RNA (SNP) | VAF 36/517 reads (7%) | called by muse, mutect2
- KCNQ3 | c.387-1031A>T | Intron (SNP) | VAF 27/416 reads (6%) | called by muse, mutect2
- LIM2 | c.175+65A>T | Intron (SNP) | VAF 50/578 reads (9%) | called by muse, mutect2
- OFCC1 | n.161T>C | RNA (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- OR56B3P | n.506G>C | RNA (SNP) | VAF 14/179 reads (8%) | catalogued as rs747411341; called by muse, mutect2
- PAX4 | c.772-15G>C | Intron (SNP) | VAF 43/175 reads (25%) | catalogued as rs780379553; called by muse, mutect2, varscan2
- RNF212 | c.247-2898G>T | Intron (SNP) | VAF 40/338 reads (12%) | catalogued as COSV61363682; called by muse, mutect2, varscan2
- RPLP0P2 | n.939C>T | RNA (SNP) | VAF 58/521 reads (11%) | catalogued as rs374527830; called by muse, mutect2, varscan2
- RUSC1 | c.-87+299A>T | Intron (SNP) | VAF 6/124 reads (5%) | catalogued as COSV52738104; called by muse, mutect2
- SLC39A7 | chr6:33200794 C>A | 5'Flank (SNP) | VAF 46/646 reads (7%) | called by muse, mutect2
- SYCE1 | chr10:133568018 G>T | 5'Flank (SNP) | VAF 18/75 reads (24%) | catalogued as rs1287056004; called by muse, mutect2
- SZRD1 | c.52-3738A>G | Intron (SNP) | VAF 111/526 reads (21%) | called by muse, mutect2, varscan2
- TPP1 | c.89+25C>T | Intron (SNP) | VAF 76/356 reads (21%) | called by muse, mutect2, varscan2
- TTYH1 | c.1033-10C>T | Intron (SNP) | VAF 36/292 reads (12%) | called by muse, mutect2, varscan2
- YARS1 | c.821-28T>G | Intron (SNP) | VAF 33/385 reads (9%) | called by muse, mutect2
- ZEB2 | c.73+4796A>T | Intron (SNP) | VAF 30/290 reads (10%) | called by muse, mutect2
- ZFPM2 | n.259T>C | RNA (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2
